Surgical pathology report (de-identified scan), TCGA case TCGA-B0-5692, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B0-5692-01A (Primary Tumor).

PATIENT HISTORY:

The patient is a [REDACTED]

PRE-OP DIAGNOSIS: Right renal carcinoma

POST-OP DIAGNOSIS: Same

PROCEDURE: Right nephrectomy

FINAL DIAGNOSIS:**RIGHT KIDNEY, NEPHRECTOMY -**

- A. RENAL CELL CARCINOMA, CONVENTIONAL (CLEAR CELL) TYPE
B. THE TUMOR IS 8.2 cm IN GREATEST DIMENSION.
C. FUHRMAN'S NUCLEAR GRADE 3 OF 4.
D. INVASION BY RENAL CELL CARCINOMA OF A LARGE, MUSCLE CONTAINING, SEGMENT OF OF RENAL VEIN IS IDENTIFIED (SECTION D).
E. INVASION OF PERINEPHRIC ADIPOSE TISSUE IS IDENTIFIED.
F. ALL SURGICAL MARGINS ARE FREE OF NEOPLASIA.
G. NON-NEOPLASTIC RENAL PARENCHYMA SHOWS CHRONIC INTERSTITIAL INFLAMMATION AND SOME SCLEROTIC GLOMERULI.
H. PATHOLOGIC TNM STAGING: pT3b Nx Mx.
- A. Side: 1 1. Right 2. Left
B. Location: 1
1. Kidney (parenchyma - cortex/medulla) 3. Ureter
2. Kidney (pelvis) 4. Kidney and ureter
C. Procedure: 2
1. Partial nephrectomy 4. Ureterectomy
2. Simple nephrectomy 5. Other
3. Radical nephrectomy
D. Size of neoplasm (maximum dimension; if multicentric, size of largest mass): 8.2 cm
E. Type of malignant neoplasm: 1
1. Renal cell carcinoma, clear cell type 11. Urothelial carcinoma, small cell/neuroendocrine carcinoma
(includes non-papillary granular cell RCC)
2. Renal cell carcinoma, chromophil cell type 12. Urothelial carcinoma, mixed
(papillary RCC, no clear cell component)
3. Renal cell carcinoma, chromophobe cell type 13. Juxtaglomerular cell tumor
4. Renal cell carcinoma, oncocytic 14. Wilms' tumor
15. Rhabdoid tumor
16. Clear cell sarcoma
17. Congenital mesoblastic nephroma
5. Renal cell carcinoma, sarcomatoid 18. Sarcoma (non-clear cell)
6. Collecting duct carcinoma
7. Urothelial carcinoma, TCCa 19. Lymphoma/leukemia
(non-invasive) 20. Other
8. Urothelial carcinoma, TCCa
(invasive ± in-situ)
9. Urothelial carcinoma, squamous carcinoma
10. Urothelial carcinoma, adenocarcinoma
F. Histologic grade
F1. Fuhrman grade (for RCC; grades 1-4): 3
F2. Ash grade (grade 1-4): NA
F3. WHO grade (grade 1-3): NA (for TCCa)
F4. 1998 WHO/ISUP Classification: NA
1. LMP 2. LG 3. HG
F5. Other malignant neoplasms (grades 1-3): NA
G. Non-neoplastic and other conditions:
1. Glomerulopathy
2. Interstitial nephritis
3. Pyelonephritis
4. Nephrolithiasis
5. Papillary necrosis
6. Chronic parenchymal disease
7. Other
H. Margins of resection: 2 1. Positive 2. Negative
I. Mitotic activity: 1 per 10 high power fields
J. Angiolymphatic invasion
J1. Macroscopic (e.g., renal vein thrombus): 1 1. Positive 2. Negative
J2. Microscopic: 2 1. Positive 2. Negative
K. Number of positive lymph nodes: NA
L. Total number of lymph nodes examined: 0
M. Extracapsular spread of lymph node metastases: NA
1. Yes 2. No
N. Adrenal gland:
N1. Present 2 1. Yes 2. No
N2. Involvement by renal neoplasm: 3 1. Yes 2. No 3. Not Applicable
N3. Other adrenal pathology: 3 1. Yes 2. No 3. Not applicable
O. TNM stage: T 3b N x M x

Source: NCI Genomic Data Commons file 7287b804-8f7d-4b3d-8c0f-3602e4d0da82 (TCGA-B0-5692.C1B80A45-AA5A-46AC-AE76-7091A5074D01.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).